Somatic mutation profile of tumor specimen TARGET-20-PASSVI-09A (aliquot TARGET-20-PASSVI-09A-01D) from TARGET case TARGET-20-PASSVI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.7 years (5,752 days).
Specimen TARGET-20-PASSVI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d56bc4d1-01f8-4a97-a789-bcf906b8fd43.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASSVI-10A (Blood Derived Normal), aliquot TARGET-20-PASSVI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b329f3f6-d76c-47a2-9ff4-321f28613f9b

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRXN1 | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 89/242 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs980499901, COSV58446649; called by muse, mutect2
- SRCAP | c.4084C>T p.R1362* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2, varscan2
